Somatic mutation profile of tumor specimen TCGA-G6-A8L8-01A (aliquot TCGA-G6-A8L8-01A-21D-A36X-10) from TCGA case TCGA-G6-A8L8, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 62.0 years (22,649 days).
Specimen TCGA-G6-A8L8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c5606b8-7977-4389-b4ff-68d97872aff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G6-A8L8-10A (Blood Derived Normal), aliquot TCGA-G6-A8L8-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c955c84-b5fd-4029-853e-ce872808ee4a

The open-access MAF lists 79 somatic variants for this specimen: 64 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 14, Frame Shift Del 8, Nonsense Mutation 4, Splice Site 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAS1 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 147/393 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs148582842; called by muse, mutect2, varscan2
- BHMT | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs768147946, COSV99165366; called by muse, mutect2, varscan2
- CACNA1F | c.1797T>A p.F599L | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV100544330; called by muse, mutect2, varscan2
- CAP2 | c.581A>T p.E194V | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100012032; called by muse, mutect2, varscan2
- CD34 | c.74T>A p.L25* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100178106; called by muse, mutect2, varscan2
- CELF6 | c.143T>A p.L48H | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763552; called by muse, mutect2
- CELSR2 | c.5608A>T p.I1870F | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs767768147, COSV99602972; called by muse, mutect2, varscan2
- CNTNAP4 | c.3207C>G p.I1069M | Missense Mutation (SNP) | VAF 6/176 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100269205, COSV56671446, COSV56671531; called by muse, mutect2
- COL6A1 | c.2779T>C p.Y927H | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as COSV100719883; called by muse, mutect2, varscan2
- COL8A1 | c.1284G>C p.K428N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99657116; called by muse, mutect2, varscan2
- EBNA1BP2 | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.85); PolyPhen benign (0.119); catalogued as COSV99355808; called by muse, mutect2, varscan2
- EDIL3 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs757863733, COSV56879041; called by muse, mutect2, varscan2
- EDNRB | c.1345G>A p.E449K (on ENST00000377211 / NM_001201397.1; = p.E359K on NM_000115.5) | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as CM101986, COSV57521513; called by muse, mutect2, varscan2
- EFCAB13 | c.2180T>G p.I727S | Missense Mutation (SNP) | VAF 100/216 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV100516321; called by muse, mutect2, varscan2
- EN2 | c.320G>A p.S107N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV99818548; called by muse, mutect2
- ERICH3 | c.4430G>A p.G1477E | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs542267741, COSV58604371; called by muse, mutect2, varscan2
- FBXL13 | c.15G>T p.L5F | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100501099; called by muse, mutect2, varscan2
- FCRL3 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.229); catalogued as rs559562792, COSV100943629, COSV63840816; called by muse, mutect2, varscan2
- FERMT1 | c.482T>A p.I161N | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.085); catalogued as rs185559251, COSV99451004; called by muse, mutect2, varscan2
- GLYR1 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1180548945, COSV100424019; called by muse, mutect2, varscan2
- GOLGA4 | c.4784A>G p.Y1595C | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100728631; called by muse, mutect2, varscan2
- HCRTR2 | c.535G>C p.V179L | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.401); catalogued as COSV100904117; called by muse, mutect2, varscan2
- IL5RA | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 73/109 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV99842620; called by muse, mutect2, varscan2
- INIP | c.260A>T p.D87V | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100954087; called by muse, mutect2, varscan2
- INIP | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100954088; called by muse, mutect2, varscan2
- INVS | c.2747del p.K916Rfs*27 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | catalogued as COSV99317384; called by mutect2, pindel, varscan2
- LETM1 | c.2204C>A p.A735E | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.502); catalogued as COSV100245161; called by muse, varscan2
- LMTK3 | c.3277C>T p.P1093S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV99539907; called by muse, mutect2, varscan2
- LPAR2 | c.951G>C p.Q317H | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101345477; called by muse, mutect2, varscan2
- LRRIQ1 | c.2038A>G p.R680G | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as rs1258872431, COSV101279422; called by muse, mutect2
- LYN | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.131); catalogued as COSV101319562; called by muse, mutect2, varscan2
- MYH4 | c.5078G>T p.R1693M | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99700272; called by muse, mutect2, varscan2
- NAGA | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.093); catalogued as COSV101124130; called by muse, mutect2
- NCF2 | c.415A>C p.K139Q | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100838861; called by muse, mutect2, varscan2
- NFIL3 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99906771; called by muse, mutect2, varscan2
- NOX5 | c.206_207insCTATCTATGACTCCTATTCTATCTA p.D70Yfs*3 | Nonsense Mutation (INS) | VAF 32/124 reads (26%) | catalogued as COSV99533208; called by mutect2, pindel
- OR2J2 | c.709A>C p.K237Q | Missense Mutation (SNP) | VAF 127/318 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV101013269; called by muse, mutect2, varscan2
- OXER1 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99685200; called by muse, mutect2, varscan2
- PARD3 | c.2599G>A p.D867N | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.112); catalogued as COSV100400150; called by muse, mutect2, varscan2
- PBRM1 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 94/153 reads (61%) | catalogued as COSV56284753; called by muse, mutect2, varscan2
- PCDHGA11 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99529764; called by muse, mutect2
- PSMC5 | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1293865113, COSV99856183; called by muse, mutect2, varscan2
- RBM12B | c.1047A>C p.Q349H | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.815); catalogued as COSV101197120; called by muse, mutect2, varscan2
- RNF6 | c.804G>T p.R268S | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100644571; called by muse, mutect2
- SIDT2 | c.2388C>A p.H796Q | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54057357, COSV99637067; called by muse, mutect2, varscan2
- TBKBP1 | c.1663C>G p.P555A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.242); catalogued as COSV100659002; called by muse, mutect2, varscan2
- TLR4 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.386); catalogued as rs537921979, CM035919, COSV100790590; called by muse, mutect2, varscan2
- TNMD | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100887786; called by muse, mutect2, varscan2
- TYK2 | c.1471A>T p.S491C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV99314166; called by muse, mutect2, varscan2
- VHL | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 29/46 reads (63%) | catalogued as CM982011, COSV56543469, COSV56551494; called by muse, mutect2, varscan2
- VPS4A | c.440_443dup p.K148Nfs*60 | Frame Shift Ins (INS) | VAF 14/23 reads (61%) | catalogued as rs779459037; called by mutect2, varscan2
- WIPF1 | c.683C>G p.T228S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV99767854; called by muse, mutect2, varscan2
- ZAN | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.755); catalogued as rs1475605521, COSV100769081; called by muse, mutect2, varscan2
- ZFP57 | c.1031A>C p.Q344P | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100971795; called by muse, varscan2
- ZNF623 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101513459; called by muse, mutect2, varscan2
- ABCA7 | c.4502del p.P1501Qfs*17 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- CDCP2 | c.1350del p.*450Yfs*47 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | called by muse*, pindel
- COL4A3 | c.2489del p.X830_splice | Splice Site (DEL) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- GXYLT2 | c.402del p.F134Lfs*16 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | called by mutect2, pindel, varscan2
- HDAC9 | c.2494del p.Y832Mfs*39 | Frame Shift Del (DEL) | VAF 91/298 reads (31%) | called by mutect2, pindel, varscan2
- LAMC3 | c.2872del p.S958Pfs*63 | Frame Shift Del (DEL) | VAF 56/152 reads (37%) | called by mutect2, pindel, varscan2
- PHF21A | c.1147del p.I383Sfs*32 (on ENST00000418153 / NM_001101802.3; = p.I384Sfs*32 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 72/265 reads (27%) | called by mutect2, pindel, varscan2
- SIGLEC10 | c.1082del p.N361Tfs*30 | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | called by mutect2, pindel, varscan2
- VEGFB | c.393_410+12del p.X131_splice | Splice Site (DEL) | VAF 22/112 reads (20%) | called by mutect2, pindel
- CAPN5 | c.1974G>A p.R658= (on ENST00000456580; = p.R618= on NM_004055.5) | Silent (SNP) | VAF 4/61 reads (7%) | catalogued as COSV99581678; called by muse, mutect2
- CDKL5 | c.579C>T p.D193= | Silent (SNP) | VAF 183/464 reads (39%) | catalogued as COSV101184006; called by muse, mutect2, varscan2
- DNAH11 | c.5727C>T p.A1909= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as COSV100176787; called by muse, mutect2, varscan2
- GFRAL | c.1002A>G p.K334= | Silent (SNP) | VAF 66/590 reads (11%) | catalogued as COSV100474490; called by muse, mutect2, varscan2
- IFT172 | c.1026A>C p.S342= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as COSV99561698; called by muse, mutect2, varscan2
- LAD1 | c.1287T>G p.T429= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV100943777; called by muse, mutect2, varscan2
- LMTK3 | c.1809C>A p.G603= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV99539910; called by muse, mutect2, varscan2
- LYSMD1 | c.120G>T p.L40= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as COSV99765851; called by muse, mutect2, varscan2
- MCM7 | c.525C>T p.P175= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100384568; called by muse, mutect2, varscan2
- MEGF10 | c.3324T>C p.P1108= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV99174692; called by muse, mutect2, varscan2
- MYCT1 | c.663C>T p.P221= | Silent (SNP) | VAF 40/58 reads (69%) | catalogued as rs761292156, COSV100924022; called by muse, mutect2, varscan2
- NEUROD6 | c.48G>A p.Q16= | Silent (SNP) | VAF 68/166 reads (41%) | catalogued as COSV99773837; called by muse, mutect2, varscan2
- PKHD1L1 | c.6627T>C p.D2209= | Silent (SNP) | VAF 50/143 reads (35%) | catalogued as COSV101005254; called by muse, mutect2, varscan2
- TBC1D8B | c.153T>C p.D51= | Silent (SNP) | VAF 74/179 reads (41%) | catalogued as COSV99343829; called by muse, mutect2, varscan2
- PARGP1 | n.1015G>A | RNA (SNP) | VAF 137/474 reads (29%) | catalogued as rs1422130852; called by muse, mutect2, varscan2
